Somatic mutation profile of tumor specimen SM-JU32T (aliquot 7316UP-2843) from CPTAC case C846363, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU32T: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7401899f-f8ae-40a4-a2ad-32b477061891.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105216 (Blood Derived Normal), aliquot 7316UP-2100-1105216; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f929da2-e855-410a-b300-a47855ccba8f

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Frame Shift Del 5, Nonsense Mutation 5, Intron 4, 5'Flank 3, Frame Shift Ins 2, 5'UTR 2, RNA 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG12 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 138/894 reads (15%) | PolyPhen probably damaging (1); catalogued as rs553349150; called by muse, mutect2, varscan2
- ANK1 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs764141047, COSV55886773; called by muse, mutect2, varscan2
- CABP2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs375360165, COSV53708769; called by muse, mutect2, varscan2
- CCDC63 | c.1454G>A p.W485* | Nonsense Mutation (SNP) | VAF 24/334 reads (7%) | catalogued as rs750494632; called by muse, mutect2
- CD163L1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 120/416 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs779416105, COSV58016469; called by muse, mutect2, varscan2
- CDS1 | c.642C>T p.F214= | Splice Region (SNP) | VAF 12/60 reads (20%) | catalogued as rs375840719; called by muse, mutect2, varscan2
- CHP2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs756989190, COSV55649492; called by muse, mutect2, varscan2
- CYP46A1 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99029145; called by muse, mutect2, varscan2
- DDX19B | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.812); catalogued as rs1342443178; called by muse, mutect2, varscan2
- DEFB114 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs141697166, COSV59038413; called by muse, mutect2, varscan2
- DSC2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs374707462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.975); catalogued as COSV101260742; called by muse, mutect2
- DSP | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 316/897 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs777847026; called by muse, mutect2, varscan2
- KEL | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 57/615 reads (9%) | catalogued as COSV100787323; called by muse, mutect2
- KMT2D | c.7864G>A p.D2622N | Missense Mutation (SNP) | VAF 75/408 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs760968358; called by muse, mutect2, varscan2
- LAMB1 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 24/152 reads (16%) | catalogued as rs1370434147, COSV55963202, COSV55969793; called by muse, mutect2
- LARP1B | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs150798326; called by muse, mutect2, varscan2
- LRGUK | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs764953610, COSV53633892; called by muse, mutect2, varscan2
- LRP1B | c.12207C>G p.N4069K | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV67257448; called by muse, mutect2
- MMP3 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as rs149156238; called by muse, mutect2, varscan2
- MRGPRX4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778327061, COSV58589894; called by muse, mutect2, varscan2
- NIPA2 | c.995A>G p.N332S | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1329526188; called by muse, mutect2, varscan2
- NIPSNAP2 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 114/557 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753851867; called by muse, mutect2, varscan2
- OR7C1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs772802995, COSV50183672; called by muse, mutect2
- PFAS | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 107/321 reads (33%) | catalogued as rs368793879; called by muse, mutect2, varscan2
- PHETA1 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.217); catalogued as rs1490105994; called by muse, mutect2
- PIK3R1 | c.1915C>T p.R639* (on ENST00000521381 / NM_181523.3; = p.R369* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 55/233 reads (24%) | catalogued as COSV57126125; called by muse, mutect2, varscan2
- TLR4 | c.2372G>A p.R791K (on ENST00000355622 / NM_138554.5; = p.R751K on NM_003266.4) | Missense Mutation (SNP) | VAF 65/570 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV100842898; called by muse, mutect2, varscan2
- TTN | c.87049G>A p.E29017K (on ENST00000591111; = p.E21593K on NM_003319.4) | Missense Mutation (SNP) | VAF 83/265 reads (31%) | PolyPhen probably damaging (0.994); catalogued as COSV60229470; called by muse, mutect2, varscan2
- AC005324.2 | c.1080_1084del p.E361Qfs*12 | Frame Shift Del (DEL) | VAF 36/345 reads (10%) | called by mutect2, varscan2
- AC013489.1 | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ARRDC4 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); called by muse, varscan2
- ASB2 | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CMSS1 | c.350del p.L117Rfs*12 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- CRISP3 | c.367A>G p.T123A (on ENST00000371159 / NM_001368123.1; = p.T105A on NM_006061.4) | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- DOCK3 | c.4613A>G p.N1538S | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ERGIC2 | c.909_910del p.V304Yfs*2 | Frame Shift Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, varscan2
- EYA1 | c.482C>G p.T161R | Missense Mutation (SNP) | VAF 178/500 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FHAD1 | c.1712C>A p.A571D | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2
- FRS3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- FUT8 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.53); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCAR3 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 141/436 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- IGSF9 | c.357dup p.D120Rfs*5 | Frame Shift Ins (INS) | VAF 33/268 reads (12%) | called by mutect2, pindel, varscan2
- LILRA5 | c.313del p.S105Pfs*2 | Frame Shift Del (DEL) | VAF 93/725 reads (13%) | called by mutect2, pindel, varscan2
- MGAM2 | c.4807G>T p.D1603Y | Missense Mutation (SNP) | VAF 47/636 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NPDC1 | c.910C>G p.P304A | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- OR13F1 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.573); called by muse, varscan2
- OR2B11 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T10 | c.319T>G p.L107V | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR4Q3 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOA | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PGC | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by muse, mutect2
- PRKDC | c.11884C>T p.R3962W | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN23 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RNF207 | c.1487G>C p.W496S | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- RTF1 | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SHISA6 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2
- SLC38A1 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLCO5A1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SLIT2 | c.3718T>G p.F1240V | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TACC1 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TENT4B | c.1160dup p.L388Pfs*25 (on ENST00000561678 / NM_001365323.2; = p.L373Pfs*25 on NM_001040284.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 38/219 reads (17%) | called by mutect2, pindel, varscan2
- TRUB1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.27314G>A p.G9105D (on ENST00000591111; = p.G8178D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/419 reads (35%) | PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- URB2 | c.4496_4505del p.D1499Gfs*33 | Frame Shift Del (DEL) | VAF 67/466 reads (14%) | called by mutect2, pindel*, varscan2*
- USP6 | c.125A>C p.N42T | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIRP1 | c.3596G>T p.C1199F | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF174 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 98/495 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ZNF507 | c.1772T>C p.I591T | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM18 | c.1164A>G p.Q388= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.5808A>G p.R1936= (on ENST00000310343 / NM_001378025.1; = p.R1587= on NM_014715.4) | Silent (SNP) | VAF 144/356 reads (40%) | called by muse, mutect2, varscan2
- FGF6 | c.591G>A p.P197= | Silent (SNP) | VAF 88/241 reads (37%) | catalogued as rs776204115; called by muse, mutect2, varscan2
- FRS3 | c.741C>T p.T247= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs770198041; called by muse, mutect2, varscan2
- GOT1L1 | c.198G>A p.L66= | Silent (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- HFM1 | c.4131T>A p.I1377= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- KRTAP13-2 | c.204G>A p.T68= | Silent (SNP) | VAF 85/240 reads (35%) | catalogued as rs746030923; called by muse, mutect2, varscan2
- LY86 | c.69T>A p.G23= | Silent (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- NXF1 | c.1473G>C p.L491= | Silent (SNP) | VAF 57/171 reads (33%) | called by muse, mutect2, varscan2
- PKP2 | c.2070C>T p.I690= | Silent (SNP) | VAF 167/611 reads (27%) | catalogued as rs538127756, COSV50755620; called by muse, mutect2, varscan2
- SENP3 | c.1455T>C p.R485= | Silent (SNP) | VAF 24/186 reads (13%) | catalogued as rs1381389986; called by muse, mutect2, varscan2
- SLC1A7 | c.375G>A p.T125= | Silent (SNP) | VAF 83/465 reads (18%) | catalogued as rs371121273; called by muse, mutect2, varscan2
- SLC4A10 | c.315C>T p.T105= | Silent (SNP) | VAF 56/216 reads (26%) | catalogued as rs374865086; called by muse, mutect2, varscan2
- SYNDIG1L | c.705C>T p.N235= | Silent (SNP) | VAF 147/342 reads (43%) | catalogued as rs764855912, COSV100526538; called by muse, mutect2, varscan2
- TAAR9 | c.519C>T p.N173= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs372695882, COSV71512268; called by muse, mutect2, varscan2
- TUBA4A | c.162T>C p.C54= | Silent (SNP) | VAF 49/458 reads (11%) | called by muse, mutect2, varscan2
- AIP | c.*34C>T | 3'UTR (SNP) | VAF 51/402 reads (13%) | called by muse, mutect2, varscan2
- CDH15 | chr16:89168442 T>A | 5'Flank (SNP) | VAF 6/145 reads (4%) | called by muse, mutect2
- DPF3 | chr14:72894105 del AG | 5'Flank (DEL) | VAF 55/149 reads (37%) | catalogued as rs766420993; called by mutect2, pindel*, varscan2
- EPS8L2 | c.895+72A>C | Intron (SNP) | VAF 18/95 reads (19%) | catalogued as rs753850480; called by muse, mutect2, varscan2
- FAM183BP | n.459C>T | RNA (SNP) | VAF 44/182 reads (24%) | catalogued as rs777630638; called by muse, mutect2, varscan2
- FAM197Y1 | n.374G>A | RNA (SNP) | VAF 42/852 reads (5%) | catalogued as rs776135058; called by muse, mutect2
- FTH1 | chr11:61968275 T>C | 5'Flank (SNP) | VAF 18/331 reads (5%) | called by muse, mutect2
- GALNT9 | c.1077+270G>A | Intron (SNP) | VAF 53/182 reads (29%) | catalogued as rs1429858126; called by muse, mutect2, varscan2
- GPI | c.123-349G>A | Intron (SNP) | VAF 72/431 reads (17%) | called by muse, mutect2, varscan2
- MSH2 | c.-19G>C | 5'UTR (SNP) | VAF 87/598 reads (15%) | catalogued as rs1237109405; called by muse, mutect2, varscan2
- PPP4R3A | c.1266+21T>G | Intron (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2
- PRKCG | c.-132C>A | 5'UTR (SNP) | VAF 49/372 reads (13%) | called by muse, mutect2, varscan2
